MMRF case MMRF_2539 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/86144286-8390-4e67-9bbb-7d6fde5cc6eb

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 51.8 years (18,918 days); ISS stage: II; Days to last known disease status: 654 days (1.8 years); Days to last follow up: 654 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 117 days; Days to treatment end: 117 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -14 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3694 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 0.13 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 3.82 µg/mL; Lactate Dehydrogenase 8.15 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 297 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 7.43 mmol/L.
- Day 84 (ECOG 0): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 4.23 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 7.07 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 503 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.38 mmol/L.
- Day 177 (ECOG 1): Hemoglobin 7.25 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 264 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.83 mmol/L.
- Day 262 (ECOG 0): Hemoglobin 7.19 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 128 ×10⁹/L.
- Day 374 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.77 mg/dL; Immunoglobulin G 7.43 g/L; Immunoglobulin A 0.4 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 7 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.34 mmol/L.
- Day 507 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 7.84 g/L; Immunoglobulin A 1.08 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 1.88 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 132 ×10⁹/L.
- Day 654 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.677 mg/dL; Immunoglobulin G 7.11 g/L; Immunoglobulin A 0.514 g/L; Immunoglobulin M 0.234 g/L; Lactate Dehydrogenase 6.3 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 123 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.08 mmol/L; Albumin 40 g/L; Total Protein 6.1 g/dL; Glucose 5.72 mmol/L.

Other clinical attributes
- Day -14: Weight: 78 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Paternal Grandmother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (3 samples)
- Sample MMRF_2539_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -14 days.
- Sample MMRF_2539_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -14 days.
- Sample MMRF_2539_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 84 days.
